Gene-level copy-number profile of tumor specimen TCGA-OR-A5J5-01A from TCGA case TCGA-OR-A5J5, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 30.6 years (11,171 days).
Specimen TCGA-OR-A5J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.9e704a46-2d0c-48c9-a6fa-1566d67a75e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5J5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/32034942-3a8a-4816-a82c-6c3c526c890d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 23; copy number 2: 33,161; copy number 3: 7,665; copy number 4: 18,458; copy number 5: 413; copy number 7: 81; copy number 8: 4; copy number 11: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5J5-01A-11D-A29H-01): tumor purity 0.93, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 513 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:101,976,296–101,976,798, 1 gene, copy number 8: AC117525.1.
- chr5:119,629,559–128,189,677, 110 genes, copy number 5–8 (broad region; genes not listed).
- chr7:150,746,893–159,233,377, 159 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–10,612,723, 147 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr9:101,322,477–101,563,344, 14 genes, copy number 11: AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20.
- chr9:101,591,604–101,595,021, 1 gene, copy number 11: PPP3R2.
- chr13:111,095,838–114,337,626, 81 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
